Somatic mutation profile of tumor specimen TCGA-MV-A51V-01A (aliquot TCGA-MV-A51V-01A-11D-A26M-08) from TCGA case TCGA-MV-A51V, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 75.1 years (27,430 days).
Specimen TCGA-MV-A51V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81ad6718-6c22-4648-8b49-af821a6396f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MV-A51V-10A (Blood Derived Normal), aliquot TCGA-MV-A51V-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19cd871e-036a-4788-9b01-2970a0a7b4e2

The open-access MAF lists 1,703 somatic variants for this specimen: 1,297 protein-altering or splice-affecting, 364 silent, 42 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,145, Silent 364, Nonsense Mutation 117, Intron 21, Splice Site 20, RNA 9, Splice Region 5, Nonstop Mutation 4, 3'UTR 4, 3'Flank 4, Frame Shift Del 3, 5'UTR 3.

Variants (750 of 1,703; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2305G>T p.D769Y | Missense Mutation (SNP) | VAF 28/62 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913468, COSV54062373, COSV54062425, COSV54063143; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NIPBL | c.1576C>T p.Q526* | Nonsense Mutation (SNP) | VAF 38/455 reads (8%) | catalogued as rs587783889, COSV99238546; ClinVar: pathogenic; called by muse, mutect2
- A2M | c.337G>C p.E113Q | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as COSV59388760, COSV59389701; called by muse, mutect2, varscan2
- AADACL4 | c.1136C>G p.S379C | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV66106656; called by muse, mutect2
- AAK1 | c.2824G>C p.E942Q | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101296159; called by muse, mutect2
- ABCA13 | c.4352C>G p.S1451* | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | catalogued as COSV101329906; called by muse, mutect2
- ABCA13 | c.10279C>G p.L3427V | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.465); catalogued as COSV71290655; called by muse, mutect2, varscan2
- ABCA2 | c.3322G>C p.D1108H (on ENST00000614293; = p.D1078H on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.828); catalogued as COSV55803211, COSV55803778; called by muse, mutect2
- ABCC2 | c.3864G>T p.K1288N | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.055); catalogued as COSV100966369; called by muse, mutect2
- ABCC3 | c.3241G>C p.E1081Q | Missense Mutation (SNP) | VAF 28/290 reads (10%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.456); catalogued as COSV53324554; called by muse, mutect2
- ABCD2 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.133); catalogued as rs368375856, COSV100429817; called by muse, mutect2, varscan2
- ABCG5 | c.1894C>G p.P632A | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV53182558, COSV99570828; called by muse, mutect2, varscan2
- ABRAXAS2 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.624); catalogued as COSV53717579; called by muse, mutect2, varscan2
- AC004922.1 | c.532G>T p.E178* | Nonsense Mutation (SNP) | VAF 25/134 reads (19%) | catalogued as COSV99500904; called by muse, mutect2, varscan2
- AC023055.1 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.942); catalogued as COSV60243627; called by mutect2, varscan2
- ACAD11 | c.2049G>T p.K683N | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as rs1456912128, COSV53898272; called by muse, mutect2, varscan2
- ACAP2 | c.1611G>C p.K537N | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as COSV58753270; called by muse, mutect2, varscan2
- ACD | c.1120G>A p.E374K (on ENST00000620338; = p.E285K on NM_022914.3) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs200298308, COSV54668663; called by muse, mutect2, varscan2
- ACOT7 | c.841C>T p.H281Y (on ENST00000377855 / NM_181864.3; = p.H271Y on NM_007274.4) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.072); catalogued as COSV64114159, COSV64114878; called by muse, mutect2, varscan2
- ACP1 | c.23C>A p.S8Y | Missense Mutation (SNP) | VAF 13/244 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV55243920; called by muse, mutect2
- ACR | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.116); catalogued as rs368710046, COSV53360743; called by muse, mutect2, varscan2
- ACSL3 | c.1585C>G p.L529V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.042); catalogued as rs1368243457, COSV62483247; called by muse, mutect2, varscan2
- ACSL4 | c.1603G>C p.E535Q (on ENST00000340800 / NM_022977.2; = p.E494Q on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.038); catalogued as COSV61614965; called by muse, mutect2
- ACSM2A | c.142A>G p.S48G | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1371787027, COSV54586366; called by muse, mutect2, varscan2
- ACSS3 | c.480G>C p.L160F | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV99698224; called by muse, mutect2
- ACTN1 | c.901G>C p.V301L | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as rs1488723977, COSV51993946; called by muse, mutect2, varscan2
- ACTR1A | c.419C>G p.S140C | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV64023601, COSV64023965; called by muse, mutect2, varscan2
- ACTR3B | c.67G>A p.G23S | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as COSV99753533; called by muse, mutect2, varscan2
- ACTRT1 | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 53/109 reads (49%) | catalogued as COSV100947496; called by muse, mutect2, varscan2
- ACVR2B | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.37); catalogued as COSV61702734; called by muse, mutect2, varscan2
- ADAM10 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53052589; called by muse, mutect2
- ADAM22 | c.724G>C p.E242Q | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55981210, COSV55993475; called by muse, varscan2
- ADAM9 | c.1939C>G p.Q647E | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV65960996; called by muse, mutect2
- ADAMTS20 | c.169C>T p.Q57* | Nonsense Mutation (SNP) | VAF 13/114 reads (11%) | catalogued as COSV101238809; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2006C>T p.A669V | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (1); PolyPhen possibly damaging (0.597); catalogued as rs935774818, COSV54455156; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1219G>C p.E407Q | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55002071, COSV55004699; called by muse, varscan2
- ADCY1 | c.2146C>T p.R716C | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs781610623, COSV52037170; called by muse, mutect2, varscan2
- ADCY10 | c.3670C>G p.L1224V | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100896536; called by muse, mutect2, varscan2
- ADCY10 | c.2215G>C p.E739Q | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs1407377211, COSV63242047, COSV63242814; called by muse, mutect2
- ADD3 | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as COSV99523140; called by muse, mutect2
- ADGRG4 | c.1959G>C p.E653D | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV54960370; called by muse, mutect2, varscan2
- ADGRV1 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV101315421; called by muse, varscan2
- ADIPOR2 | c.593C>T p.S198L | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63946254; called by muse, mutect2, varscan2
- ADPRM | c.552G>T p.M184I | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV65754863; called by muse, mutect2, varscan2
- AFAP1L1 | c.1879G>C p.E627Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.575); catalogued as COSV57046134; called by muse, mutect2, varscan2
- AFF4 | c.2912C>G p.S971* | Nonsense Mutation (SNP) | VAF 5/62 reads (8%) | catalogued as COSV99534524; called by muse, mutect2
- AFF4 | c.254C>G p.S85* | Nonsense Mutation (SNP) | VAF 24/63 reads (38%) | catalogued as COSV99534526; called by muse, mutect2, varscan2
- AFG3L2 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as COSV52315502; called by muse, mutect2, varscan2
- AGTR2 | c.461G>T p.R154I | Missense Mutation (SNP) | VAF 124/136 reads (91%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV64156647; called by muse, mutect2, varscan2
- AHNAK | c.3325G>A p.D1109N | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV57218360, COSV99950125; called by muse, mutect2, varscan2
- AHNAK | c.2776G>A p.E926K | Missense Mutation (SNP) | VAF 67/244 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.96); catalogued as COSV57218377; called by muse, mutect2, varscan2
- AKAP6 | c.6661A>T p.R2221* | Nonsense Mutation (SNP) | VAF 9/51 reads (18%) | catalogued as COSV99797961; called by muse, mutect2, varscan2
- AKAP6 | c.6662G>A p.R2221K | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as rs746856340, COSV55219663; called by muse, mutect2, varscan2
- AKAP9 | c.7231C>G p.Q2411E (on ENST00000359028; = p.Q2387E on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.152); catalogued as COSV62350339; called by muse, mutect2, varscan2
- AKAP9 | c.10165G>C p.E3389Q (on ENST00000359028; = p.E3365Q on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.936); catalogued as COSV100662437, COSV62346073, COSV62350356; called by muse, mutect2, varscan2
- AKNAD1 | c.2377G>C p.E793Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.048); catalogued as COSV64172666; called by muse, mutect2
- AKNAD1 | c.1852G>C p.E618Q | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV62199997; called by muse, mutect2, varscan2
- AKNAD1 | c.822G>C p.K274N | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777288194, COSV62200016; called by muse, mutect2, varscan2
- ALCAM | c.577G>C p.D193H | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV60250710; called by muse, mutect2, varscan2
- ALMS1 | c.9974C>T p.S3325L | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.541); catalogued as rs754690894, COSV52513528; called by muse, mutect2, varscan2
- ALS2CL | c.1942G>C p.E648Q | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.186); catalogued as COSV59672182; called by muse, mutect2, varscan2
- AMDHD2 | c.126G>C p.E42D | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as rs769452568, COSV99565573; called by muse, mutect2
- AMPD2 | c.2038C>G p.P680A | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56648694; called by muse, mutect2
- ANAPC1 | c.2536C>T p.Q846* | Nonsense Mutation (SNP) | VAF 12/60 reads (20%) | catalogued as COSV100594490; called by muse, varscan2
- ANAPC5 | c.1064C>T p.S355F | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV55843501; called by muse, mutect2, varscan2
- ANAPC7 | c.486C>G p.I162M | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV71443877; called by muse, mutect2, varscan2
- ANGEL2 | c.424G>C p.D142H | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV64737090; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4780G>T p.D1594Y | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV51851273; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5222G>C p.R1741T | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99781916; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.6718G>A p.D2240N | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.453); catalogued as COSV51851284; called by muse, mutect2, varscan2
- ANKRD12 | c.3274G>T p.E1092* | Nonsense Mutation (SNP) | VAF 26/222 reads (12%) | catalogued as COSV100040640; called by muse, mutect2, varscan2
- ANKRD13B | c.874C>A p.L292I | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61471303; called by muse, mutect2, varscan2
- ANKRD30A | c.1043G>A p.G348E (on ENST00000611781; = p.G292E on NM_052997.2) | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); catalogued as COSV64613875; called by muse, mutect2, varscan2
- ANKRD35 | c.1220C>G p.S407* | Nonsense Mutation (SNP) | VAF 9/78 reads (12%) | catalogued as COSV100841620; called by muse, mutect2, varscan2
- ANKS1A | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.98); catalogued as rs762103309, COSV64461964; called by muse, mutect2, varscan2
- ANO4 | c.1276G>C p.A426P (on ENST00000392977 / NM_001286615.2; = p.A391P on NM_178826.4) | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV54601831; called by muse, mutect2, varscan2
- ANO8 | c.189G>C p.E63D | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV50184806; called by muse, mutect2, varscan2
- ANXA9 | c.931G>C p.E311Q | Missense Mutation (SNP) | VAF 67/303 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV56499532; called by muse, mutect2, varscan2
- ANXA9 | c.1037G>T p.*346Lext*35 | Nonstop Mutation (SNP) | VAF 51/203 reads (25%) | catalogued as COSV100385235; called by muse, mutect2, varscan2
- AP1M2 | c.660C>A p.F220L | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.232); catalogued as COSV51568027; called by muse, mutect2, varscan2
- AP3B1 | c.827C>G p.S276C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54888175, COSV99670591; called by muse, mutect2
- AP3S2 | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.038); catalogued as COSV60518832; called by muse, mutect2, varscan2
- AP5M1 | c.823C>G p.L275V | Missense Mutation (SNP) | VAF 13/183 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.047); catalogued as COSV55105837; called by muse, mutect2
- APBA3 | c.73C>G p.L25V | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV57463061, COSV57463535; called by muse, mutect2, varscan2
- APBB1 | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV54977746; called by muse, mutect2, varscan2
- APC | c.6550G>C p.E2184Q | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV57355891; called by muse, mutect2, varscan2
- APOB | c.11662G>C p.E3888Q | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.139); catalogued as COSV51941473; called by muse, mutect2
- APOBEC3C | c.346C>A p.L116I | Missense Mutation (SNP) | VAF 55/180 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53327162; called by muse, mutect2, varscan2
- APOE | c.949C>T p.H317Y | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.059); catalogued as COSV52985893; called by muse, mutect2, varscan2
- ARHGAP12 | c.1105G>C p.D369H | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60964381; called by muse, mutect2, varscan2
- ARHGAP17 | c.671G>C p.R224T | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV99252805; called by muse, mutect2
- ARHGAP18 | c.286C>G p.Q96E | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV63765017; called by muse, mutect2, varscan2
- ARHGEF11 | c.3044C>T p.S1015F | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV59355690; called by muse, mutect2, varscan2
- ARHGEF16 | c.1678G>C p.E560Q | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.057); catalogued as COSV65682463; called by muse, mutect2
- ARHGEF26 | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 5/71 reads (7%) | catalogued as rs370676439; called by muse, mutect2
- ARID1A | c.1519C>T p.Q507* | Nonsense Mutation (SNP) | VAF 218/404 reads (54%) | catalogued as COSV61372392, COSV61377138; called by muse, mutect2, varscan2
- ARIH2 | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100711351, COSV62705278; called by muse, mutect2, varscan2
- ARIH2 | c.1180C>T p.Q394* | Nonsense Mutation (SNP) | VAF 20/63 reads (32%) | catalogued as COSV100711174; called by muse, mutect2, varscan2
- ARL13A | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as rs369115223, COSV65880286; called by muse, varscan2
- ARMH4 | c.1840G>C p.E614Q | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.698); catalogued as COSV50767085; called by muse, mutect2, varscan2
- ASB6 | c.1012C>G p.Q338E | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.01); catalogued as COSV52965315; called by muse, mutect2, varscan2
- ASIC1 | c.1176G>T p.K392N | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV57318754; called by muse, mutect2, varscan2
- ASPM | c.7035C>G p.F2345L | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.907); catalogued as COSV54132777; called by muse, mutect2, varscan2
- ASPM | c.5380C>G p.Q1794E | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as COSV54132787; called by muse, mutect2
- ASPM | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.067); catalogued as COSV54129115, COSV54132798; called by muse, mutect2, varscan2
- ASTN2 | c.2661G>C p.E887D (on ENST00000313400 / NM_001365069.1; = p.E836D on NM_014010.5) | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV57791315; called by muse, mutect2, varscan2
- ASTN2 | c.2047G>C p.E683Q (on ENST00000313400 / NM_001365069.1; = p.E632Q on NM_014010.5) | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.196); catalogued as COSV100524355; called by muse, mutect2
- ATAD5 | c.5068G>A p.D1690N | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58976062; called by muse, mutect2, varscan2
- ATAD5 | c.5350C>G p.L1784V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.265); catalogued as COSV58976069; called by muse, mutect2, varscan2
- ATG13 | c.794C>G p.S265* | Nonsense Mutation (SNP) | VAF 37/156 reads (24%) | catalogued as COSV100365468, COSV100365497, COSV56318903; called by muse, mutect2, varscan2
- ATG2B | c.2258C>G p.S753C | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV63424071; called by muse, mutect2
- ATM | c.418G>C p.D140H | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs55633650, COSV53753248; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP1A3 | c.132+1G>T p.X44_splice (on ENST00000545399 / NM_001256214.2; = p.X31_splice on NM_152296.5) | Splice Site (SNP) | VAF 55/510 reads (11%) | catalogued as COSV57488854; called by muse, mutect2, varscan2
- ATP2A2 | c.104G>C p.R35T | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV100428370; called by muse, mutect2
- ATP2C1 | c.2098A>G p.K700E | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV60758492; called by muse, mutect2
- ATP8A2 | c.2050C>G p.Q684E | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54961019; called by muse, mutect2
- ATPAF2 | c.6G>C p.W2C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV99254027; called by muse, varscan2
- ATXN1 | c.1372C>T p.Q458* | Nonsense Mutation (SNP) | VAF 51/196 reads (26%) | catalogued as COSV99784815; called by muse, mutect2, varscan2
- ATXN7L3 | c.228C>A p.F76L | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV66989303; called by muse, varscan2
- AXIN2 | c.2455G>C p.E819Q | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.858); catalogued as COSV61057820; called by muse, mutect2
- AZIN1 | c.1127G>T p.G376V | Missense Mutation (SNP) | VAF 92/166 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61480567; called by muse, mutect2, varscan2
- B3GALNT2 | c.1361G>T p.R454I | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV64004199; called by muse, mutect2, varscan2
- BAAT | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as rs1475294284, COSV52289798; called by muse, mutect2
- BABAM2 | c.496-1G>C p.X166_splice | Splice Site (SNP) | VAF 3/14 reads (21%) | catalogued as COSV100567224; called by muse, mutect2
- BBS7 | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV52657598; called by muse, mutect2
- BBX | c.1645G>C p.E549Q | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.46); catalogued as COSV57887965; called by muse, mutect2
- BCL9 | c.1808G>A p.R603Q | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); catalogued as rs782091140, COSV52342408; called by muse, mutect2, varscan2
- BFAR | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as COSV55493587; called by muse, mutect2, varscan2
- BICRA | c.2675C>G p.S892C | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV67605258; called by muse, mutect2, varscan2
- BIRC6 | c.10477C>A p.H3493N | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV70201172; called by muse, mutect2
- BMP15 | c.1023G>C p.Q341H | Missense Mutation (SNP) | VAF 12/167 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53140931; called by muse, mutect2
- BMP6 | c.559C>G p.L187V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.194); catalogued as COSV99306265; called by muse, varscan2
- BNIP5 | c.205C>T p.H69Y | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV71325646; called by muse, mutect2, varscan2
- BORCS5 | c.292G>C p.D98H | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.062); catalogued as rs761039053, COSV53803395; called by muse, mutect2, varscan2
- BPIFB6 | c.1261C>T p.Q421* | Nonsense Mutation (SNP) | VAF 24/150 reads (16%) | catalogued as COSV100848477; called by muse, varscan2
- BRAT1 | c.2308G>A p.E770K | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV61396008; called by muse, mutect2, varscan2
- BRCA2 | c.4552G>C p.E1518Q | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.233); catalogued as CM023342, COSV66456639, COSV66458002; called by muse, mutect2, varscan2
- BRINP1 | c.649C>T p.L217F | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56300908; called by muse, mutect2
- BRPF1 | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 10/254 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); catalogued as COSV57406028; called by muse, mutect2
- BSN | c.5268G>C p.Q1756H | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV56521557; called by muse, mutect2
- BTN2A1 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.048); catalogued as COSV57004296; called by muse, mutect2, varscan2
- BTN3A3 | c.1660C>G p.L554V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV55072593; called by muse, mutect2, varscan2
- BTNL8 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1249057419, COSV51459614; called by mutect2, varscan2
- BUB1 | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 27/189 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.808); catalogued as COSV57064883; called by muse, mutect2, varscan2
- BUB1B | c.1726G>C p.D576H | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as COSV55014053; called by muse, mutect2, varscan2
- C15orf40 | c.280C>G p.P94A | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58450003; called by muse, mutect2, varscan2
- C1orf105 | c.322G>C p.E108Q | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.033); catalogued as COSV100877911; called by muse, mutect2
- C20orf194 | c.1447C>T p.Q483* | Nonsense Mutation (SNP) | VAF 12/108 reads (11%) | catalogued as COSV99330220; called by muse, mutect2, varscan2
- C21orf58 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV52450368; called by muse, mutect2, varscan2
- C2orf15 | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 10/90 reads (11%) | catalogued as COSV100208908; called by muse, mutect2, varscan2
- C2orf16 | c.3182C>G p.S1061C | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV62676696; called by muse, mutect2, varscan2
- C2orf16 | c.5745G>A p.M1915I | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.062); catalogued as COSV62676699; called by muse, mutect2, varscan2
- C4orf50 | c.460C>G p.Q154E (on ENST00000324058; = p.Q1386E on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV60689291; called by muse, mutect2, varscan2
- C6 | c.2065G>C p.D689H | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54712618; called by muse, mutect2
- C8orf37 | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 58/338 reads (17%) | catalogued as COSV99713072; called by muse, mutect2, varscan2
- C8orf74 | c.399G>C p.Q133H | Missense Mutation (SNP) | VAF 35/242 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as COSV58754737; called by muse, mutect2, varscan2
- CACNA1F | c.4699G>C p.D1567H | Missense Mutation (SNP) | VAF 10/171 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as CD1514230, COSV59905250; called by muse, mutect2
- CACNG4 | c.496G>C p.D166H | Missense Mutation (SNP) | VAF 20/362 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV50925907; called by muse, mutect2
- CACNG5 | c.284-1G>C p.X95_splice | Splice Site (SNP) | VAF 9/147 reads (6%) | catalogued as COSV99047980; called by muse, mutect2
- CADM4 | c.1158C>G p.F386L | Missense Mutation (SNP) | VAF 44/219 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV55929254; called by muse, varscan2
- CAMK4 | c.103G>T p.D35Y | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV56675295, COSV56680559; called by muse, mutect2, varscan2
- CAMTA2 | c.1666C>T p.P556S | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs151058277; called by muse, mutect2, varscan2
- CAND1 | c.3611C>G p.S1204C | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs1396666122, COSV73389677; called by muse, mutect2
- CARD6 | c.1780C>G p.Q594E | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.824); catalogued as COSV54567172; called by muse, mutect2, varscan2
- CARF | c.2168C>G p.S723C | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV57548364; called by muse, mutect2
- CARMIL1 | c.4099G>C p.E1367Q | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.38); catalogued as COSV61519781; called by muse, mutect2, varscan2
- CARS2 | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 14/78 reads (18%) | catalogued as COSV99959340; called by muse, mutect2, varscan2
- CBLB | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV51430063; called by muse, mutect2
- CCDC102B | c.625G>C p.D209H | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.488); catalogued as COSV60146024; called by muse, mutect2, varscan2
- CCDC158 | c.964C>G p.L322V | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV66356495; called by muse, varscan2
- CCDC158 | c.913C>T p.Q305* | Nonsense Mutation (SNP) | VAF 16/92 reads (17%) | catalogued as COSV101187138; called by muse, mutect2, varscan2
- CCDC180 | c.2345G>A p.G782E | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV63830143, COSV63831813; called by muse, mutect2, varscan2
- CCDC180 | c.4099G>C p.D1367H | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV63831822; called by muse, mutect2
- CCDC183 | c.1311G>C p.L437F | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.234); catalogued as COSV61037054; called by muse, mutect2
- CCDC198 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99371111; called by muse, mutect2
- CCDC88A | c.670C>G p.L224V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.062); catalogued as COSV55064538; called by muse, mutect2, varscan2
- CCDC88C | c.4675G>A p.E1559K | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.257); catalogued as rs761127230, COSV57797167; called by muse, mutect2, varscan2
- CCHCR1 | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 14/279 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.047); catalogued as COSV66184161; called by muse, mutect2
- CCNE2 | c.838G>T p.D280Y | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100353611; called by muse, mutect2
- CCNF | c.1838C>G p.S613C | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53540993; called by muse, mutect2, varscan2
- CCNT2 | c.2148C>G p.F716L | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV51471949, COSV51474347, COSV99750253; called by muse, mutect2, varscan2
- CD93 | c.1852G>C p.E618Q | Missense Mutation (SNP) | VAF 66/260 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV55663356, COSV55666402; called by muse, mutect2, varscan2
- CDC42SE1 | c.121C>G p.H41D | Missense Mutation (SNP) | VAF 36/271 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV61785591; called by muse, mutect2, varscan2
- CDC7 | c.1480G>A p.D494N | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV52311297; called by muse, mutect2
- CDCA5 | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51870009, COSV99298084; called by muse, mutect2, varscan2
- CDCP1 | c.1508C>G p.S503C | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as rs749688848, COSV56106385; called by muse, mutect2, varscan2
- CDH15 | c.43-1G>A p.X15_splice | Splice Site (SNP) | VAF 20/97 reads (21%) | catalogued as COSV57023799, COSV57025507; called by muse, mutect2, varscan2
- CDH17 | c.1507G>C p.D503H | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as rs753350744, COSV50331671; called by muse, mutect2, varscan2
- CDH18 | c.2284C>T p.Q762* | Nonsense Mutation (SNP) | VAF 13/102 reads (13%) | catalogued as COSV99931832, COSV99934322; called by muse, mutect2, varscan2
- CDH2 | c.1397A>T p.N466I | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99295527; called by muse, mutect2
- CDHR3 | c.1246G>T p.E416* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as rs372371724, COSV100487913; called by muse, varscan2
- CDK11A | c.161G>C p.R54T | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); catalogued as COSV62265955; called by muse, mutect2, varscan2
- CDK12 | c.1375G>C p.D459H | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.896); catalogued as COSV71001414; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4550G>C p.R1517T | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV62575564; called by muse, mutect2
- CDKL5 | c.892C>G p.Q298E | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.097); catalogued as COSV66111962; called by muse, mutect2, varscan2
- CDS2 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 26/221 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV66896903; called by muse, mutect2, varscan2
- CEACAM19 | c.346G>C p.D116H | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62552117; called by muse, mutect2, varscan2
- CEL | c.1378G>C p.D460H (on ENST00000673714; = p.D457H on NM_001807.6) | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60826641, COSV60828243; called by muse, mutect2, varscan2
- CELF3 | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 84/148 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51883410; called by muse, mutect2, varscan2
- CEMIP2 | c.1296G>C p.Q432H | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV65488014; called by muse, mutect2
- CENPA | c.392G>T p.R131M | Missense Mutation (SNP) | VAF 28/276 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51982961; called by muse, mutect2
- CENPI | c.1905G>C p.K635N | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.076); catalogued as COSV54503934; called by muse, mutect2
- CEP104 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs771819433, COSV58215077; called by muse, mutect2, varscan2
- CEP44 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as COSV56659827; called by muse, mutect2, varscan2
- CEP97 | c.1078C>T p.Q360* | Nonsense Mutation (SNP) | VAF 6/55 reads (11%) | catalogued as COSV100511513; called by muse, mutect2, varscan2
- CFAP251 | c.280G>C p.E94Q | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.093); catalogued as COSV55839929, COSV55840214; called by muse, mutect2, varscan2
- CFAP251 | c.1939G>C p.E647Q | Missense Mutation (SNP) | VAF 96/345 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as COSV56612159; called by muse, varscan2
- CFAP47 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 40/57 reads (70%) | SIFT tolerated (0.73); PolyPhen benign (0.03); catalogued as COSV52881044; called by muse, mutect2, varscan2
- CFL2 | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.166); catalogued as COSV53311817; called by muse, mutect2, varscan2
- CGRRF1 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV53597241; called by muse, mutect2, varscan2
- CHL1 | c.1728G>C p.L576F (on ENST00000397491 / NM_001253387.1; = p.L592F on NM_006614.4) | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV56597004, COSV56598675; called by muse, mutect2
- CHMP2A | c.608C>G p.S203* | Nonsense Mutation (SNP) | VAF 9/160 reads (6%) | catalogued as COSV99447896; called by muse, mutect2
- CHPF | c.1366G>A p.D456N | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60535496; called by muse, mutect2, varscan2
- CHST15 | c.85C>G p.H29D | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.068); catalogued as COSV100655169, COSV60563370; called by muse, mutect2, varscan2
- CILP2 | c.1480C>G p.L494V | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.101); catalogued as COSV52273388; called by muse, mutect2, varscan2
- CKAP5 | c.2033C>T p.S678L | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); catalogued as COSV56369850; called by muse, mutect2, varscan2
- CKMT2 | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54173925; called by muse, mutect2, varscan2
- CLASP2 | c.2525C>T p.S842L | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56285975; called by muse, mutect2, varscan2
- CLDN18 | c.168G>C p.Q56H | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.476); catalogued as rs912287789, COSV51736960; called by muse, mutect2, varscan2
- CLEC4A | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.208); catalogued as COSV57562217; called by muse, mutect2, varscan2
- CLEC4F | c.1163G>C p.R388T | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV55479074, COSV55480119; called by muse, mutect2
- CLHC1 | c.952G>T p.A318S | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as COSV68464365; called by muse, mutect2, varscan2
- CLIP2 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782270028, COSV56281292; called by muse, mutect2
- CLOCK | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as rs1479782437, COSV100011545; called by muse, mutect2
- CNTLN | c.3420G>C p.E1140D | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52074601, COSV52084495; called by muse, mutect2
- CNTNAP2 | c.208+2T>C p.X70_splice | Splice Site (SNP) | VAF 4/27 reads (15%) | catalogued as COSV100662308; called by muse, mutect2
- COBL | c.3678C>G p.F1226L | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.104); catalogued as COSV54349707; called by muse, mutect2, varscan2
- COBL | c.3439G>C p.E1147Q | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV54349717; called by muse, mutect2, varscan2
- COG5 | c.1741G>C p.D581H (on ENST00000347053 / NM_001379512.1; = p.D602H on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV51755778; called by muse, mutect2, varscan2
- COL11A1 | c.1896G>T p.M632I | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.113); catalogued as COSV100614905; called by muse, varscan2
- COL12A1 | c.5039C>T p.S1680L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV100485315; called by muse, mutect2, varscan2
- COL28A1 | c.1253G>C p.G418A | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV68083020; called by muse, mutect2, varscan2
- COL3A1 | c.2404G>A p.E802K | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58591510; called by muse, varscan2
- COL5A2 | c.3365G>A p.G1122E | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100879976; called by muse, mutect2, varscan2
- COL9A1 | c.2630G>A p.R877Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.328); catalogued as rs1408064118, COSV57884180; called by muse, mutect2, varscan2
- COL9A1 | c.529G>T p.D177Y | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV61834314; called by muse, mutect2, varscan2
- COPS3 | c.1153G>C p.E385Q | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as COSV52006222; called by muse, mutect2
- COQ4 | c.551G>A p.W184* | Nonsense Mutation (SNP) | VAF 13/106 reads (12%) | catalogued as COSV100306598; called by muse, mutect2, varscan2
- CORO2B | c.529G>T p.D177Y | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV55953295, COSV55958509; called by muse, mutect2, varscan2
- COX5A | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV59279604; called by muse, mutect2, varscan2
- CPA2 | c.310G>T p.E104* | Nonsense Mutation (SNP) | VAF 8/75 reads (11%) | catalogued as COSV55979431, COSV99743725; called by muse, mutect2, varscan2
- CPD | c.2729C>T p.S910L | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs1208591515, COSV56711055, COSV56715139; called by muse, mutect2
- CPNE8 | c.1625G>C p.R542P | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as COSV58841994, COSV58845984; called by mutect2, varscan2
- CPT2 | c.1540G>C p.E514Q | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV99598025; called by muse, mutect2
- CRACD | c.361C>G p.P121A | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV51724913; called by muse, mutect2
- CRK | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as COSV56031231; called by muse, mutect2, varscan2
- CRK | c.283G>C p.D95H | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV56031240; called by muse, mutect2
- CRTC1 | c.578C>A p.S193* | Nonsense Mutation (SNP) | VAF 44/299 reads (15%) | catalogued as COSV100118989; called by muse, mutect2, varscan2
- CRYBG3 | c.6702G>C p.K2234N | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51713368; called by muse, mutect2, varscan2
- CRYGS | c.245C>G p.S82C | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57192031, COSV57192639; called by muse, mutect2, varscan2
- CSDE1 | c.1828C>T p.P610S (on ENST00000358528 / NM_001007553.3; = p.P579S on NM_007158.6) | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV54751252; called by muse, mutect2, varscan2
- CSNK1G2 | c.259C>T p.H87Y | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.113); catalogued as COSV99729541; called by muse, mutect2, varscan2
- CSPP1 | c.1615C>G p.L539V (on ENST00000676605; = p.L498V on NM_024790.6) | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV51587155; called by muse, mutect2, varscan2
- CSPP1 | c.2602C>T p.Q868* (on ENST00000676605; = p.Q827* on NM_024790.6) | Nonsense Mutation (SNP) | VAF 7/146 reads (5%) | catalogued as COSV51593293; called by muse, mutect2
- CSTF2 | c.1018G>C p.E340Q | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.464); catalogued as COSV65894332; called by muse, mutect2, varscan2
- CTBS | c.1078G>C p.D360H | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV55363263; called by muse, mutect2, varscan2
- CTTNBP2NL | c.411G>C p.E137D | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1162755251, COSV54745367; called by muse, mutect2, varscan2
- CUEDC1 | c.334G>T p.E112* | Nonsense Mutation (SNP) | VAF 56/192 reads (29%) | catalogued as COSV100804645; called by muse, mutect2, varscan2
- CWF19L2 | c.2116C>G p.L706V | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV56515120; called by muse, mutect2
- CWH43 | c.758C>G p.S253C | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.163); catalogued as COSV56940415; called by muse, mutect2, varscan2
- CYFIP2 | c.3090C>G p.F1030L (on ENST00000616178 / NM_001291722.2; = p.F1005L on NM_014376.4) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.786); catalogued as COSV59043330; called by muse, mutect2, varscan2
- CYP11B2 | c.1017C>G p.I339M | Missense Mutation (SNP) | VAF 28/243 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV59996607; called by muse, mutect2, varscan2
- CYP2A6 | c.853G>C p.E285Q | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as COSV56535934, COSV99991723; called by muse, mutect2
- DAB2 | c.388G>C p.D130H | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57916018; called by muse, mutect2, varscan2
- DAG1 | c.2514G>C p.E838D | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.947); catalogued as COSV58185290; called by muse, mutect2, varscan2
- DAW1 | c.1185C>A p.F395L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV59366591; called by muse, mutect2, varscan2
- DCAF16 | c.276G>C p.E92D | Missense Mutation (SNP) | VAF 13/179 reads (7%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as COSV66384262; called by muse, mutect2
- DCDC2B | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.374); catalogued as COSV52207783, COSV52209639; called by muse, mutect2, varscan2
- DCLRE1A | c.1790C>G p.S597W | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV63749053; called by muse, mutect2, varscan2
- DCLRE1B | c.463C>G p.L155V | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); catalogued as COSV56725646; called by muse, mutect2, varscan2
- DDAH1 | c.357G>T p.M119I | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.181); catalogued as COSV52305063; called by mutect2, varscan2
- DDC | c.715-1G>C p.X239_splice | Splice Site (SNP) | VAF 13/66 reads (20%) | catalogued as COSV100779104; called by muse, mutect2
- DDI2 | c.589C>G p.P197A | Missense Mutation (SNP) | VAF 29/323 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV60780252; called by muse, mutect2
- DDIAS | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV61272530; called by muse, mutect2
- DDX46 | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV62799857; called by mutect2, varscan2
- DDX47 | c.891G>C p.M297I | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV61911662; called by muse, mutect2, varscan2
- DDX60L | c.4770C>G p.I1590M | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.336); catalogued as COSV52716273; called by muse, mutect2, varscan2
- DEDD | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 92/151 reads (61%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1381291478, COSV63502171; called by muse, mutect2, varscan2
- DEK | c.785G>C p.R262T | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.047); catalogued as COSV55238435, COSV99788641; called by muse, mutect2
- DENND4A | c.5506C>G p.Q1836E | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (1); PolyPhen possibly damaging (0.572); catalogued as COSV71266363; called by muse, mutect2
- DENND4C | c.4498G>C p.E1500Q (on ENST00000434457 / NM_001330640.2; = p.E1451Q on NM_017925.7) | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.877); catalogued as COSV63009164; called by muse, mutect2, varscan2
- DGCR6L | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV50619270; called by muse, varscan2
- DHRS2 | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51632644; called by muse, mutect2
- DHRS2 | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1232168341, COSV51630876, COSV51632605; called by muse, mutect2
- DHRS3 | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs201342762, COSV66108426; called by muse, mutect2, varscan2
- DHRS7 | c.704G>C p.G235A | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53666731; called by muse, mutect2, varscan2
- DHTKD1 | c.1753C>T p.Q585* | Nonsense Mutation (SNP) | VAF 81/154 reads (53%) | catalogued as COSV53805816, COSV99535996; called by muse, mutect2, varscan2
- DHX15 | c.231G>C p.L77F | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT tolerated (0.7); PolyPhen benign (0.076); catalogued as COSV61027940; called by muse, mutect2
- DHX8 | c.1678G>C p.E560Q | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.285); catalogued as COSV52254315; called by muse, mutect2, varscan2
- DHX8 | c.2387G>C p.R796T | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52254325; called by muse, mutect2
- DHX9 | c.2640C>G p.I880M | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV62360405; called by muse, mutect2, varscan2
- DMRT1 | c.825G>A p.M275I | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV66522452; called by muse, mutect2, varscan2
- DMXL1 | c.5078G>C p.R1693T | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60715152; called by muse, mutect2, varscan2
- DMXL2 | c.8806C>A p.H2936N | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV51849594; called by muse, mutect2, varscan2
- DNAH11 | c.10541T>A p.L3514Q | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60963895; called by muse, mutect2
- DNAH12 | c.808C>T p.L270F | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.331); catalogued as COSV60857001, COSV60858692; called by muse, mutect2
- DNAH3 | c.7132G>T p.E2378* | Nonsense Mutation (SNP) | VAF 18/102 reads (18%) | catalogued as COSV54556215, COSV99764701; called by muse, mutect2, varscan2
- DNAH3 | c.49C>G p.P17A | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV51785977; called by muse, mutect2
- DNAH9 | c.6760G>C p.E2254Q | Missense Mutation (SNP) | VAF 41/214 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV52357890, COSV52372227; called by muse, mutect2, varscan2
- DNAI1 | c.353G>C p.G118A | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV54282306; called by muse, mutect2
- DNAJB1 | c.169G>T p.D57Y | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54318141, COSV99583980; called by muse, mutect2
- DNAJB1 | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.069); catalogued as COSV54317227, COSV54317299; called by muse, mutect2, varscan2
- DNAJC10 | c.146G>C p.R49T | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV51140807, COSV51144024; called by muse, mutect2, varscan2
- DNAJC16 | c.1194G>T p.L398F | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65448912, COSV65449578; called by muse, mutect2
- DNASE1L3 | c.537G>A p.W179* | Nonsense Mutation (SNP) | VAF 14/190 reads (7%) | catalogued as COSV59156850; called by muse, mutect2
- DOCK9 | c.3420G>C p.K1140N (on ENST00000376460 / NM_001366676.2; = p.K1141N on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV59634209; called by muse, mutect2, varscan2
- DOK5 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs780293083, COSV52819629; called by muse, mutect2, varscan2
- DPF2 | c.1172C>G p.S391C | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.7); catalogued as rs1453519526, COSV52888062; called by muse, mutect2
- DPY19L2 | c.1680G>C p.L560F | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.477); catalogued as COSV61043313; called by muse, mutect2, varscan2
- DRC7 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.059); catalogued as COSV61056049; called by muse, mutect2, varscan2
- DROSHA | c.2107C>G p.L703V | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV100757450, COSV60778468; called by muse, mutect2, varscan2
- DUS1L | c.594G>A p.R198= | Splice Region (SNP) | VAF 14/122 reads (11%) | catalogued as COSV57649792; called by muse, mutect2, varscan2
- DUSP16 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53807099; called by muse, mutect2
- DVL1 | c.1507+1G>C p.X503_splice (on ENST00000378888 / NM_001330311.2; = p.X478_splice on NM_004421.3) | Splice Site (SNP) | VAF 4/45 reads (9%) | catalogued as COSV100229234; called by muse, mutect2
- DYM | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53987644; called by muse, mutect2, varscan2
- DYNC1H1 | c.8576C>T p.P2859L | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as rs1273252656, COSV64138602; called by muse, mutect2
- DYRK2 | c.1481G>C p.R494T (on ENST00000344096 / NM_006482.3; = p.R421T on NM_003583.4) | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as COSV59846710; called by muse, mutect2
- DYTN | c.268C>G p.L90V | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV101510797, COSV71752565; called by muse, mutect2
- E2F5 | c.534C>G p.I178M | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs774880479, COSV56275418, COSV56276255; called by muse, mutect2, varscan2
- ECPAS | c.3517C>T p.R1173* | Nonsense Mutation (SNP) | VAF 4/21 reads (19%) | catalogued as COSV52191969; called by muse, mutect2, varscan2
- ECPAS | c.1061A>C p.D354A | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as COSV52200826; called by muse, mutect2, varscan2
- EFCAB12 | c.658G>C p.E220Q | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.189); catalogued as COSV58177190; called by muse, mutect2, varscan2
- EGFR | c.1169A>G p.Q390R | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV51815409; called by muse, mutect2, varscan2
- EGLN1 | c.1253C>T p.S418L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.225); catalogued as rs779990034, COSV64149770; called by mutect2, varscan2
- EHBP1 | c.464C>G p.S155C | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50424666; called by muse, mutect2, varscan2
- EHBP1L1 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1279762999; called by muse, mutect2
- EHMT1 | c.1346G>C p.R449T | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as COSV58377298; called by muse, mutect2
- EIF2S3 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV53407132; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100349210; called by muse, mutect2
- EIF4G3 | c.1847C>G p.T616S | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV51686519; called by muse, mutect2
- ELMOD3 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.037); catalogued as COSV59773540; called by muse, mutect2, varscan2
- ELP2 | c.1126-1G>A p.X376_splice | Splice Site (SNP) | VAF 5/69 reads (7%) | catalogued as COSV60852094; called by muse, mutect2
- EML3 | c.2479C>G p.R827G | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV53872966; called by muse, mutect2, varscan2
- EPB41L4B | c.845G>C p.R282T | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs190636972, COSV65797565; called by muse, mutect2, varscan2
- EPG5 | c.7297G>C p.E2433Q | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as COSV56351826; called by muse, mutect2, varscan2
- EPHA5 | c.1188G>C p.K396N | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV56653868, COSV56674477; called by muse, mutect2, varscan2
- EPHB1 | c.563C>G p.S188C | Missense Mutation (SNP) | VAF 15/235 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV67654980, COSV67659512, COSV67664485; called by muse, mutect2
- EPHB3 | c.1515G>A p.M505I | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV57807143; called by muse, mutect2, varscan2
- EPHB6 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 103/313 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1355721144, COSV67418268, COSV67419244; called by muse, mutect2, varscan2
- EPS8 | c.2449G>C p.D817H | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as COSV55529604; called by muse, mutect2
- ERBB3 | c.1227C>A p.F409L | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV57256951; called by muse, mutect2, varscan2
- ERCC2 | c.630C>G p.H210Q | Missense Mutation (SNP) | VAF 52/97 reads (54%) | SIFT tolerated (0.56); PolyPhen benign (0.019); catalogued as COSV55542265; called by muse, mutect2, varscan2
- EREG | c.482C>G p.S161* | Nonsense Mutation (SNP) | VAF 9/147 reads (6%) | catalogued as COSV55261886; called by muse, mutect2
- ESCO1 | c.1057C>G p.Q353E | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV52520696; called by muse, mutect2, varscan2
- ESX1 | c.611G>C p.R204T | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as COSV65424646; called by muse, mutect2
- ETV6 | c.1260G>T p.M420I | Missense Mutation (SNP) | VAF 14/360 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.353); catalogued as COSV56766157; called by muse, mutect2
- EVI5L | c.1759G>C p.E587Q | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.205); catalogued as COSV99562840; called by muse, mutect2
- EXOC5 | c.767G>C p.R256T | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV61771330; called by muse, mutect2, varscan2
- EYA4 | c.1026C>G p.I342M (on ENST00000531901 / NM_001301013.1; = p.I336M on NM_004100.5) | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.564); catalogued as COSV62048657; called by muse, mutect2
- F10 | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM025195, COSV65022032, COSV65022246; called by muse, mutect2, varscan2
- F5 | c.2919C>G p.I973M | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV63125523; called by muse, mutect2
- F7 | c.777G>C p.K259N | Missense Mutation (SNP) | VAF 57/190 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV60646646; called by muse, mutect2, varscan2
- FAM114A2 | c.1239G>C p.R413S | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV61078222; called by muse, varscan2
- FAM131A | c.321G>C p.W107C (on ENST00000310585; = p.W138C on NM_144635.5) | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55602247; called by muse, mutect2
- FAM193A | c.1069G>T p.D357Y | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV61195922; called by muse, mutect2, varscan2
- FAM217A | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763255944, COSV51160928; called by muse, mutect2, varscan2
- FAM53C | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as COSV53512193; called by muse, mutect2, varscan2
- FAM71B | c.1633C>G p.P545A | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV57229782, COSV57230751; called by muse, mutect2
- FAM71F2 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV66352238; called by muse, mutect2, varscan2
- FAM98A | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.35); catalogued as COSV53210910, COSV53212148; called by muse, mutect2, varscan2
- FANCF | c.1010G>T p.G337V | Missense Mutation (SNP) | VAF 11/165 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59416545; called by muse, mutect2
- FAT3 | c.7876G>C p.D2626H | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99961393; called by muse, mutect2
- FAXC | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV67602670; called by muse, mutect2, varscan2
- FBF1 | c.3389C>G p.S1130C (on ENST00000586717; = p.S1145C on NM_001319193.1) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as COSV100044694; called by muse, mutect2, varscan2
- FBN1 | c.3346G>C p.E1116Q | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57321306; called by muse, mutect2
- FBN1 | c.2795C>T p.S932L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57321314; called by muse, mutect2, varscan2
- FBXL4 | c.1256T>C p.F419S | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV57747866; called by muse, mutect2
- FBXL5 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV58012225; called by muse, varscan2
- FBXL5 | c.242C>G p.S81C | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58012235; called by muse, varscan2
- FBXL7 | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61643063; called by muse, mutect2
- FBXO41 | c.1909G>A p.A637T | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.085); catalogued as COSV99720821; called by muse, mutect2
- FBXO5 | c.524C>G p.S175C | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV57671172; called by muse, mutect2
- FBXW10 | c.2973G>C p.K991N | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV57060305; called by muse, mutect2, varscan2
- FEM1C | c.571G>C p.E191Q | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV57232009; called by muse, mutect2, varscan2
- FERMT3 | c.1834G>C p.E612Q (on ENST00000279227 / NM_178443.3; = p.E608Q on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.995); catalogued as COSV54174432; called by muse, mutect2, varscan2
- FGD3 | c.23C>G p.S8* | Nonsense Mutation (SNP) | VAF 5/29 reads (17%) | catalogued as COSV100490363; called by muse, mutect2
- FGD6 | c.2740G>C p.E914Q | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100676549, COSV59694477; called by muse, mutect2, varscan2
- FGGY | c.1655G>C p.*552Sext*28 | Nonstop Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as COSV100363671; called by muse, mutect2, varscan2
- FILIP1L | c.1996G>A p.E666K (on ENST00000354552 / NM_182909.3; = p.E426K on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV58771335; called by muse, mutect2
- FLAD1 | c.270G>C p.Q90H | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV99422012, COSV99422559; called by muse, mutect2
- FLG | c.10657G>C p.E3553Q | Missense Mutation (SNP) | VAF 44/522 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.298); catalogued as COSV64243647; called by muse, mutect2
- FLG | c.9550G>A p.E3184K | Missense Mutation (SNP) | VAF 45/640 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.164); catalogued as COSV64243651; called by muse, mutect2
- FLG2 | c.3980C>G p.S1327C | Missense Mutation (SNP) | VAF 83/312 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV66169900; called by muse, mutect2, varscan2
- FLI1 | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as COSV55645873; called by muse, mutect2
- FLNB | c.2368G>A p.E790K | Missense Mutation (SNP) | VAF 29/218 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.155); catalogued as rs1392670034, COSV55884348; called by muse, mutect2, varscan2
- FLNB | c.7240C>T p.P2414S | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.92); PolyPhen probably damaging (1); catalogued as COSV55884373; called by muse, mutect2, varscan2
- FLNC | c.2053G>T p.D685Y | Missense Mutation (SNP) | VAF 47/290 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV57958456; called by muse, mutect2, varscan2
- FLOT2 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as COSV67529185; called by muse, mutect2
- FNBP4 | c.2974G>C p.E992Q | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.484); catalogued as COSV54093323, COSV54093654, COSV99771372; called by muse, mutect2, varscan2
- FNIP1 | c.2704C>T p.Q902* | Nonsense Mutation (SNP) | VAF 4/54 reads (7%) | catalogued as COSV100330218; called by muse, mutect2
- FOXD4L5 | c.251C>G p.S84* | Nonsense Mutation (SNP) | VAF 30/496 reads (6%) | catalogued as COSV101073004, COSV101073240; called by muse, mutect2
- FPGT | c.1289C>G p.S430* | Nonsense Mutation (SNP) | VAF 8/66 reads (12%) | catalogued as COSV100907007; called by muse, mutect2
- FRMD4B | c.2542G>C p.E848Q | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as COSV68331219; called by mutect2, varscan2
- FRMPD4 | c.2752G>C p.E918Q | Missense Mutation (SNP) | VAF 87/232 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66217812; called by muse, mutect2, varscan2
- FRMPD4 | c.3097G>A p.D1033N | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs772365939, COSV66210829; called by muse, mutect2, varscan2
- FSIP2 | c.18109G>A p.E6037K | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as COSV58090660; called by muse, mutect2, varscan2
- FYB2 | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.643); catalogued as rs1196169776, COSV58586392; called by muse, mutect2
- FZD6 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62470685; called by muse, mutect2
- GABRB3 | c.152G>A p.G51E | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.787); catalogued as COSV59481832; called by muse, mutect2, varscan2
- GABRD | c.1075G>T p.A359S | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.998); catalogued as COSV66081103; called by muse, mutect2
- GAL3ST1 | c.1115C>G p.S372C | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV58892952; called by muse, mutect2
- GALNTL5 | c.1001G>C p.R334T | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV67180487; called by muse, mutect2, varscan2
- GARS1 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs373326652, COSV66828691; ClinVar: likely benign / uncertain significance / benign; called by muse, mutect2, varscan2
- GARS1 | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 11/66 reads (17%) | catalogued as rs767696937, COSV66827720; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GCSAM | c.72G>C p.M24I | Missense Mutation (SNP) | VAF 16/211 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV58263769; called by muse, mutect2
- GDF2 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.043); catalogued as rs41314469; ClinVar: likely benign; called by muse, mutect2, varscan2
- GDF9 | c.1333G>A p.D445N | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.503); catalogued as rs774616473, COSV51526233; called by muse, mutect2, varscan2
- GFM1 | c.1137G>C p.K379N | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); catalogued as COSV51833733; called by muse, mutect2, varscan2
- GFPT1 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0.029); catalogued as COSV61947581; called by muse, mutect2, varscan2
- GFRA3 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.052); catalogued as COSV51229263; called by muse, mutect2, varscan2
- GLDN | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.215); catalogued as rs1364305602, COSV59089034; called by muse, mutect2, varscan2
- GLDN | c.1047C>G p.F349L | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.42); catalogued as COSV59090980; called by muse, mutect2, varscan2
- GLIPR1 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV56991673; called by muse, mutect2, varscan2
- GLT8D2 | c.571C>G p.Q191E | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.09); catalogued as rs1437206094, COSV100674285, COSV62562267; called by muse, mutect2
- GLUL | c.931G>T p.D311Y | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV59382614; called by muse, mutect2, varscan2
- GNB1 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 39/300 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as COSV66099885, COSV66100937; called by muse, mutect2, varscan2
- GNB3 | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782249757, COSV51834464; called by muse, mutect2, varscan2
- GNPAT | c.11C>A p.S4Y | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.094); catalogued as rs1174942092, COSV59642587; called by muse, mutect2
- GOLGA2 | c.949G>C p.A317P | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV68597343; called by muse, mutect2
- GOLGA4 | c.290C>A p.S97Y | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62711712; called by muse, mutect2, varscan2
- GPER1 | c.974G>A p.S325N | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52469551; called by muse, mutect2
- GPR132 | c.1077C>G p.F359L | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV61678099; called by muse, mutect2, varscan2
- GPR137B | c.495C>G p.I165M | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.468); catalogued as COSV63991248; called by muse, mutect2, varscan2
- GPR149 | c.2173G>C p.E725Q | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.425); catalogued as rs1290725918, COSV67668137; called by muse, mutect2
- GPR153 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); catalogued as rs748059642, COSV64938703; called by muse, mutect2, varscan2
- GPR158 | c.2524G>A p.E842K | Missense Mutation (SNP) | VAF 13/256 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0.046); catalogued as COSV66273852; called by muse, mutect2
- GPR89B | c.129C>G p.I43M | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV100032375; called by muse, mutect2, varscan2
- GREM1 | c.187G>T p.G63W | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV55715078, COSV55715428; called by muse, mutect2, varscan2
- GRID1 | c.2005C>A p.Q669K | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV60037039; called by muse, mutect2, varscan2
- GRIN2B | c.1096C>T p.L366F | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as COSV101662896, COSV74206580; called by muse, mutect2, varscan2
- GRIP2 | c.1885G>A p.A629T (on ENST00000619221; = p.A532T on NM_001080423.4) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.263); catalogued as rs531605439, COSV56124206, COSV99816890; called by muse, varscan2
- GRK3 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.312); catalogued as COSV60797585; called by muse, mutect2, varscan2
- GRXCR1 | c.847C>T p.Q283* | Nonsense Mutation (SNP) | VAF 32/177 reads (18%) | catalogued as COSV101295608, COSV67670676; called by muse, mutect2, varscan2
- GSDME | c.930G>C p.L310F | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100742302, COSV61652148; called by muse, mutect2, varscan2
- GSTM3 | c.400G>T p.E134* | Nonsense Mutation (SNP) | VAF 13/108 reads (12%) | catalogued as COSV56662363, COSV99860138; called by muse, mutect2, varscan2
- GTDC1 | c.395C>G p.S132* | Nonsense Mutation (SNP) | VAF 5/36 reads (14%) | catalogued as COSV99599318, COSV99601355; called by muse, mutect2, varscan2
- GTF2I | c.2516C>G p.S839* (on ENST00000573035 / NM_032999.4; = p.S798* on NM_001518.5) | Nonsense Mutation (SNP) | VAF 17/53 reads (32%) | catalogued as COSV100259410; called by muse, mutect2, varscan2
- GTF3C2 | c.496C>G p.Q166E | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53127434; called by muse, mutect2, varscan2
- GTPBP1 | c.722G>A p.C241Y | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.95); catalogued as COSV53283571; called by muse, mutect2, varscan2
- GTPBP10 | c.290C>A p.S97* | Nonsense Mutation (SNP) | VAF 22/66 reads (33%) | catalogued as COSV55986428, COSV55987917; called by muse, mutect2, varscan2
- GTPBP8 | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.822); catalogued as COSV55606821, COSV55607500; called by muse, mutect2
- GUCY2D | c.2629G>C p.E877Q | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1296443886, COSV54696997; called by muse, mutect2, varscan2
- H2AC15 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 17/48 reads (35%) | catalogued as COSV100356890; called by muse, mutect2, varscan2
- H4C5 | c.73G>C p.D25H | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.43); catalogued as COSV63486336; called by muse, mutect2, varscan2
- HADH | c.62C>G p.S21W | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as COSV100531350, COSV58848876; called by muse, mutect2, varscan2
- HAO2 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.191); catalogued as COSV100377766; called by muse, mutect2
- HAUS6 | c.2437C>G p.L813V | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.058); catalogued as COSV65840265; called by muse, varscan2
- HDAC6 | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 42/61 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV61929537; called by muse, mutect2, varscan2
- HDLBP | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100191802, COSV60497826; called by muse, mutect2, varscan2
- HDLBP | c.228C>G p.I76M | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV100189792; called by muse, mutect2, varscan2
- HELZ | c.4786G>A p.E1596K | Missense Mutation (SNP) | VAF 19/208 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV62379282; called by muse, mutect2
- HELZ | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 122/314 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV62379285; called by muse, mutect2, varscan2
- HERC2 | c.10028C>T p.A3343V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.978); catalogued as COSV99870589; called by muse, mutect2
- HHIPL1 | c.677C>G p.S226W | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs759273355, COSV100415038, COSV58091614; called by muse, mutect2, varscan2
- HIF1A | c.1491G>C p.Q497H | Missense Mutation (SNP) | VAF 93/250 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV60189925; called by muse, mutect2, varscan2
- HIP1 | c.1093C>G p.Q365E | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV61184734; called by muse, mutect2
- HIRIP3 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as COSV54230770; called by muse, mutect2, varscan2
- HIRIP3 | c.407C>G p.S136* | Nonsense Mutation (SNP) | VAF 42/219 reads (19%) | catalogued as COSV54232068; called by muse, mutect2, varscan2
- HLA-G | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.608); catalogued as COSV64406129; called by muse, mutect2, varscan2
- HMCN1 | c.5913C>G p.N1971K | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.02); catalogued as rs201368468, COSV54913334; called by muse, mutect2, varscan2
- HNRNPK | c.1246G>T p.E416* | Nonsense Mutation (SNP) | VAF 5/44 reads (11%) | catalogued as COSV100698859; called by muse, mutect2, varscan2
- HPS3 | c.698G>A p.R233K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56055494; called by muse, mutect2, varscan2
- HR | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 79/92 reads (86%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as rs770494504, COSV57192138, COSV57193060; called by muse, mutect2, varscan2
- HRH1 | c.627C>G p.F209L | Missense Mutation (SNP) | VAF 11/199 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.394); catalogued as COSV67955635; called by muse, mutect2
- HSP90AA1 | c.751G>T p.E251* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as COSV99354980; called by muse, varscan2
- HSPA12B | c.1174G>C p.E392Q | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53924483, COSV53925640; called by muse, mutect2, varscan2
- HSPA14 | c.529C>T p.L177F | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV65684607; called by muse, mutect2
- HSPA1L | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 47/192 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65150358; called by muse, mutect2, varscan2
- HSPA6 | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.287); catalogued as rs763881216, COSV100553755, COSV59061575; called by muse, mutect2, varscan2
- HSPG2 | c.2085G>C p.Q695H | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV65973490; called by muse, mutect2, varscan2
- HTT | c.8521G>C p.E2841Q | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61864625; called by muse, mutect2
- IARS1 | c.1037C>A p.S346* | Nonsense Mutation (SNP) | VAF 30/85 reads (35%) | catalogued as COSV100986769; called by muse, mutect2, varscan2
- IDH1 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100575976; called by muse, mutect2
- IDI1 | c.592G>C p.D198H | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV101191125; called by muse, mutect2
- IER2 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.764); catalogued as rs1157600486, COSV99460060; called by muse, mutect2, varscan2
- IFNA5 | c.442C>G p.Q148E | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV52386954, COSV52387268; called by muse, varscan2
- IFNAR2 | c.1077G>C p.L359F | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV51616374; called by muse, mutect2, varscan2
- IFNLR1 | c.1271C>G p.S424C | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV59525021, COSV59526874; called by muse, varscan2
- IFT172 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV53135504; called by muse, mutect2, varscan2
- IFT88 | c.2188G>C p.E730Q (on ENST00000319980 / NM_001318493.2; = p.E721Q on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.986); catalogued as COSV60674701, COSV60677413; called by muse, mutect2, varscan2
- IGHV3-21 | c.155G>A p.S52N | Missense Mutation (SNP) | VAF 30/330 reads (9%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs531228990; called by muse, varscan2
- IGSF1 | c.1942G>C p.G648R | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.955); catalogued as COSV63838385; called by muse, mutect2, varscan2
- IHO1 | c.1771G>C p.D591H | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56508495; called by muse, mutect2, varscan2
- IKZF3 | c.1492C>G p.H498D | Missense Mutation (SNP) | VAF 45/238 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53103769; called by muse, mutect2, varscan2
- ING4 | c.43G>C p.E15Q | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58555486; called by muse, mutect2
- INTS1 | c.4723C>G p.P1575A | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1415583716, COSV67178163; called by muse, mutect2, varscan2
- INTS5 | c.3040C>G p.L1014V | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.118); catalogued as COSV57952228; called by muse, mutect2, varscan2
- INTS5 | c.1520C>T p.S507F | Missense Mutation (SNP) | VAF 81/146 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); catalogued as COSV57952238; called by muse, mutect2, varscan2
- INTS5 | c.593C>T p.S198L | Missense Mutation (SNP) | VAF 49/87 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as rs761969399, COSV57951245; called by muse, mutect2, varscan2
- INTU | c.1927G>C p.D643H | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV58872757; called by muse, mutect2, varscan2
- IQUB | c.1945C>G p.Q649E | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV61240313, COSV61242279; called by muse, mutect2
- IRAK2 | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 44/324 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV56532667; called by muse, mutect2, varscan2
- IRS4 | c.644G>C p.G215A | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV100929406, COSV64532542; called by mutect2, varscan2
- ITGA8 | c.2288G>A p.R763K | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs1564365219; called by muse, mutect2
- ITGA9 | c.1609G>C p.E537Q | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.105); catalogued as COSV53239692, COSV53246283; called by muse, mutect2, varscan2
- ITGB3 | c.613G>C p.D205H | Missense Mutation (SNP) | VAF 11/171 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as CD153659, COSV71384406; called by muse, mutect2
- ITIH3 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1177807333, COSV56256308; called by muse, mutect2, varscan2
- ITM2B | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV66035214, COSV66035331; called by muse, mutect2, varscan2
- ITPR1 | c.4506G>C p.L1502F (on ENST00000354582; = p.L1487F on NM_002222.7) | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56988947; called by muse, mutect2
- ITPR1 | c.6861G>A p.M2287I (on ENST00000354582; = p.M2232I on NM_002222.7) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56988970; called by muse, mutect2
- ITPR2 | c.5600T>C p.L1867S | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.631); catalogued as COSV67271553; called by muse, mutect2, varscan2
- ITPRIPL1 | c.16G>C p.E6Q (on ENST00000439118 / NM_001008949.3; = p.E14Q on NM_178495.6) | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.087); catalogued as COSV63153888; called by muse, mutect2, varscan2
- ITPRIPL1 | c.210G>T p.Q70H (on ENST00000439118 / NM_001008949.3; = p.Q78H on NM_178495.6) | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV63153899; called by muse, varscan2
- ITPRIPL1 | c.295G>A p.D99N (on ENST00000439118 / NM_001008949.3; = p.D107N on NM_178495.6) | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs369211145; called by muse, varscan2
- ITPRIPL1 | c.622G>A p.E208K (on ENST00000439118 / NM_001008949.3; = p.E216K on NM_178495.6) | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.628); catalogued as COSV63153929; called by muse, mutect2, varscan2
- ITPRIPL2 | c.1249C>A p.R417S | Missense Mutation (SNP) | VAF 31/223 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.019); catalogued as COSV67347367, COSV67347820; called by muse, mutect2, varscan2
- ITSN1 | c.329C>G p.S110C | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV66084088; called by muse, mutect2
- JAK3 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.324); catalogued as COSV71686076; called by muse, mutect2, varscan2
- JAKMIP1 | c.1804G>C p.E602Q | Missense Mutation (SNP) | VAF 65/196 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51523568, COSV51535873; called by muse, mutect2, varscan2
- KALRN | c.2446G>C p.E816Q | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV53770455; called by muse, mutect2
- KAT7 | c.1687C>T p.Q563* | Nonsense Mutation (SNP) | VAF 22/157 reads (14%) | catalogued as rs193921114, COSV52013693; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KATNB1 | c.271G>C p.D91H | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65560809; called by muse, mutect2
- KBTBD7 | c.1822G>C p.D608H | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as COSV65266748; called by muse, mutect2, varscan2
- KCNB2 | c.2297G>C p.R766T | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.063); catalogued as COSV73049023, COSV73051137; called by muse, mutect2, varscan2
- KCNG4 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57584588, COSV57585196; called by muse, mutect2
- KCNJ2 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); catalogued as COSV54662547; called by muse, mutect2
- KCNJ6 | c.964C>G p.R322G | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55711495, COSV55717209; called by muse, mutect2, varscan2
- KCNK16 | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1288837986, COSV64678518; called by muse, mutect2, varscan2
- KCTD10 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57327379; called by muse, mutect2, varscan2
- KCTD20 | c.113C>A p.S38* | Nonsense Mutation (SNP) | VAF 11/102 reads (11%) | catalogued as COSV99535747; called by muse, mutect2
- KDF1 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV57671708; called by muse, mutect2
- KDM2A | c.2978C>G p.S993C | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs1354260445, COSV58190370; called by muse, mutect2
- KIAA0100 | c.2224G>C p.A742P | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV66494332; called by muse, mutect2
- KIAA0825 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as COSV56954839; called by muse, mutect2, varscan2
- KIAA0930 | c.610C>A p.Q204K (on ENST00000336156 / NM_001009880.2; = p.Q209K on NM_015264.2) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.089); catalogued as COSV52662683, COSV52663997; called by muse, mutect2, varscan2
- KIAA1109 | c.5611G>A p.D1871N | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.346); catalogued as COSV52680220; called by muse, mutect2
- KIAA1549L | c.5380G>T p.E1794* (on ENST00000321505; = p.E2091* on NM_012194.3) | Nonsense Mutation (SNP) | VAF 13/69 reads (19%) | catalogued as COSV100380761, COSV58581613; called by muse, mutect2, varscan2
- KIAA2026 | c.518G>C p.G173A | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52390138; called by muse, mutect2, varscan2
- KIAA2026 | c.432G>C p.E144D | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs780645155, COSV52390142; called by muse, mutect2, varscan2
- KIF18A | c.1483G>C p.E495Q | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.88); PolyPhen benign (0.013); catalogued as COSV54184567; called by muse, mutect2, varscan2
- KIF22 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs369297142; called by muse, mutect2, varscan2
- KIFC3 | c.2399C>T p.S800L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs781914506, COSV65553333; called by muse, mutect2
- KIRREL1 | c.1621G>C p.E541Q | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.837); catalogued as COSV63288550; called by muse, mutect2, varscan2
- KLHL18 | c.1216G>C p.E406Q | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.763); catalogued as COSV51745066; called by muse, mutect2
- KLK3 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.793); catalogued as COSV58101258; called by muse, mutect2, varscan2
- KMT2A | c.7116G>C p.L2372F | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.085); catalogued as COSV63288128; called by muse, mutect2
- KMT2A | c.7430G>A p.R2477Q | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.074); catalogued as rs782040269, COSV63288133; called by muse, mutect2, varscan2
- KMT2C | c.12696G>C p.E4232D | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV51457901; called by muse, mutect2
- KMT2C | c.8789C>T p.S2930L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as COSV51325564, COSV51457922; called by muse, mutect2, varscan2
- KMT2C | c.8518G>A p.E2840K | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV51457939; called by muse, mutect2, varscan2
- KMT2C | c.8398G>T p.E2800* | Nonsense Mutation (SNP) | VAF 17/69 reads (25%) | catalogued as COSV100065913; called by muse, mutect2, varscan2
- KMT2C | c.8236G>A p.D2746N | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV51457964; called by muse, mutect2, varscan2
- KMT2D | c.1031C>G p.S344C | Missense Mutation (SNP) | VAF 11/183 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.72); catalogued as rs1287920288, COSV56426804, COSV56456757; called by muse, mutect2
- KMT2E | c.1152C>G p.F384L | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV57575876, COSV99996356; called by muse, varscan2
- KPNA4 | c.451C>G p.Q151E | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.403); catalogued as rs769052084, COSV62076177; called by muse, mutect2, varscan2
- KRIT1 | c.1338G>C p.Q446H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100388581; called by muse, mutect2
- KRR1 | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 10/110 reads (9%) | catalogued as COSV57517529, COSV99974646; called by muse, mutect2
- KRT19 | c.25T>C p.S9P | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1321514310, COSV64238808; called by muse, mutect2, varscan2
- KRT26 | c.268C>G p.L90V | Missense Mutation (SNP) | VAF 25/225 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56972359, COSV56973267; called by muse, mutect2, varscan2
- KRT3 | c.1366G>T p.A456S | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV58816136; called by muse, mutect2
- KRT8 | c.311C>A p.S104Y | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV53177918; called by muse, mutect2, varscan2
- KRT85 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.14); catalogued as rs773634498, COSV57737355; called by mutect2, varscan2
- KRTAP12-4 | c.179G>A p.C60Y | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as rs782754899, COSV59968160; called by muse, mutect2
- KTN1 | c.1699C>G p.L567V | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.238); catalogued as COSV101255437, COSV68024169; called by muse, mutect2, varscan2
- LAMA2 | c.1196G>C p.R399T | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69000846; called by muse, mutect2, varscan2
- LAMB1 | c.3604G>C p.E1202Q | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55966699; called by muse, mutect2
- LAMC3 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.051); catalogued as rs1044904603, COSV63090514; called by muse, mutect2, varscan2
- LARP4 | c.453C>A p.F151L | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53323995; called by muse, mutect2, varscan2
- LARS1 | c.394G>C p.E132Q (on ENST00000394434 / NM_020117.11; = p.E105Q on NM_016460.3) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV99198463; called by muse, mutect2
- LAYN | c.1050G>C p.E350D (on ENST00000375615 / NM_001258390.1; = p.E342D on NM_178834.5) | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65105028; called by muse, mutect2, varscan2
- LBR | c.1713C>G p.F571L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as rs897450329, COSV55289876; called by muse, mutect2, varscan2
- LCT | c.3525G>C p.R1175S | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV51552373; called by muse, mutect2, varscan2
- LIMA1 | c.1280G>T p.G427V | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV57966491; called by muse, mutect2
- LIMCH1 | c.1412C>T p.S471L | Missense Mutation (SNP) | VAF 18/344 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58288039; called by muse, mutect2
- LIMD1 | c.1375G>C p.E459Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.404); catalogued as COSV56268434; called by muse, varscan2
- LIN37 | c.146C>G p.S49* | Nonsense Mutation (SNP) | VAF 15/70 reads (21%) | catalogued as COSV99137374; called by muse, mutect2, varscan2
- LIN52 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as rs369694210; called by muse, mutect2, varscan2
- LMLN | c.895A>G p.R299G | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57602398; called by muse, mutect2
- LMNA | c.1969-1G>A p.X657_splice | Splice Site (SNP) | VAF 11/131 reads (8%) | catalogued as COSV61543321; called by muse, mutect2
- LMO7 | c.3395C>G p.S1132C (on ENST00000357063; = p.S813C on NM_005358.5) | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV58540724; called by muse, mutect2, varscan2
- LMTK2 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV51998713; called by muse, mutect2, varscan2
- LNPEP | c.1517C>G p.S506C | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV99183465; called by muse, mutect2
- LNX2 | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 33/247 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.063); catalogued as COSV60336657; called by muse, mutect2, varscan2
- LOX | c.1244C>T p.S415L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV50238815; called by muse, mutect2, varscan2
- LRCH3 | c.2130+8G>C | Splice Region (SNP) | VAF 54/159 reads (34%) | catalogued as COSV100604927; called by muse, mutect2, varscan2
- LRFN1 | c.1273G>C p.E425Q | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.472); catalogued as COSV50462749; called by muse, mutect2, varscan2
- LRP1 | c.2632G>C p.D878H | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV54516495; called by muse, mutect2, varscan2
- LRP2 | c.967G>C p.E323Q | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV55560094; called by muse, mutect2, varscan2
- LRRC17 | c.375C>G p.F125L | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1318359427, COSV50865705; called by muse, mutect2, varscan2
- LRRC4 | c.1133C>A p.P378H | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); catalogued as COSV50815152; called by muse, varscan2
- LRRC73 | c.76C>A p.R26S | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV99447606; called by muse, mutect2
- LRRIQ1 | c.3143C>G p.S1048* | Nonsense Mutation (SNP) | VAF 5/46 reads (11%) | catalogued as COSV101279399; called by muse, mutect2
- LRRIQ1 | c.4802G>C p.R1601T | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.038); catalogued as COSV67833226; called by muse, mutect2, varscan2
- LSS | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV62701575; called by muse, mutect2, varscan2
- LY75 | c.1897G>C p.E633Q | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.943); catalogued as COSV55108140; called by muse, mutect2, varscan2
- LY9 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 28/247 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.53); catalogued as COSV54435328; called by muse, mutect2, varscan2
- LZIC | c.508G>C p.D170H | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV65890402; called by muse, mutect2, varscan2
- MAB21L2 | c.1008G>C p.E336D | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.75); PolyPhen benign (0.014); catalogued as COSV58262432, COSV58263336; called by muse, mutect2, varscan2
- MACF1 | c.11788G>C p.E3930Q (on ENST00000372915; = p.E1863Q on NM_012090.5) | Missense Mutation (SNP) | VAF 25/145 reads (17%) | catalogued as rs1444291751, COSV57129119; called by muse, mutect2, varscan2
- MAF1 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.577); catalogued as COSV59363457; called by muse, mutect2, varscan2
- MAGEA11 | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.854); catalogued as COSV60756774, COSV60757325; called by muse, mutect2, varscan2
- MAGEC3 | c.814C>T p.Q272* | Nonsense Mutation (SNP) | VAF 29/125 reads (23%) | catalogued as COSV71610074; called by muse, mutect2, varscan2
- MAMDC2 | c.312G>C p.M104I | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV65858950; called by muse, mutect2, varscan2
- MAP10 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 59/265 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV69364038; called by muse, mutect2, varscan2
- MAP1B | c.6234G>C p.Q2078H | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.804); catalogued as rs780987966, COSV57101493; called by muse, mutect2, varscan2
- MAP1B | c.6235G>A p.D2079N | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.439); catalogued as COSV57099552, COSV57101502; called by muse, mutect2, varscan2
- MAP3K12 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as COSV57233895; called by muse, mutect2, varscan2
- MAP3K4 | c.4657C>G p.Q1553E | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62335289; called by muse, mutect2, varscan2
- MAP3K5 | c.986C>G p.S329C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV62890058; called by muse, mutect2, varscan2
- MAP7D2 | c.1009G>C p.E337Q | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV65528409; called by muse, mutect2
- MAPK13 | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV52983699; called by muse, mutect2, varscan2
- MARF1 | c.3772G>A p.E1258K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV60025376; called by muse, mutect2, varscan2
- MAT1A | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as COSV64746159; called by muse, mutect2, varscan2
- MC5R | c.819C>A p.F273L | Missense Mutation (SNP) | VAF 18/355 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61254991; called by muse, mutect2
- MCM6 | c.1321G>C p.E441Q | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51467458; called by muse, mutect2, varscan2
- MCOLN3 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.964); catalogued as rs1474719630, COSV62014871; called by muse, mutect2
- MDC1 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV64525219; called by muse, mutect2, varscan2
- MDM2 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as COSV50700370; called by muse, mutect2
- MDN1 | c.12677G>C p.R4226T | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV65521604; called by muse, mutect2, varscan2
- MDN1 | c.6174G>C p.M2058I | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); catalogued as COSV65525878; called by muse, mutect2
- MECOM | c.1381G>C p.E461Q (on ENST00000468789 / NM_001105078.4; = p.E649Q on NM_004991.4) | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV52967800; called by muse, mutect2
- MED1 | c.4316C>T p.S1439F | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV56126254; called by muse, mutect2
- MED1 | c.4088C>G p.S1363* | Nonsense Mutation (SNP) | VAF 24/233 reads (10%) | catalogued as COSV100327330; called by muse, mutect2, varscan2
- MED12L | c.2491C>G p.Q831E | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.9); catalogued as rs1560069512, COSV56384791; called by muse, mutect2, varscan2
- MED13 | c.1594C>G p.Q532E | Missense Mutation (SNP) | VAF 15/262 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.444); catalogued as COSV67264644; called by muse, mutect2
- MED13L | c.4006G>C p.D1336H | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99927724; called by muse, mutect2
- MED14 | c.3484C>G p.R1162G | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61357585, COSV61357804; called by muse, mutect2
- MED17 | c.1277G>T p.G426V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.306); catalogued as COSV52600456, COSV52601675; called by muse, mutect2, varscan2
- MED28 | c.141G>C p.E47D | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV52846698; called by muse, mutect2
- MED6 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770531881, COSV56450539; called by muse, mutect2, varscan2
- MEF2A | c.621G>C p.L207F (on ENST00000557942 / NM_001319206.2; = p.L209F on NM_005587.4 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.853); catalogued as COSV57535065; called by muse, mutect2
- MEGF10 | c.432G>C p.W144C | Missense Mutation (SNP) | VAF 14/181 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57252035; called by muse, mutect2
- MEX3A | c.1003C>T p.R335W | Missense Mutation (SNP) | VAF 137/270 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68479191; called by muse, mutect2, varscan2
- MFSD6 | c.731C>G p.S244* | Nonsense Mutation (SNP) | VAF 37/89 reads (42%) | catalogued as rs766973631, COSV99854978; called by muse, mutect2, varscan2
- MFSD6 | c.911C>A p.S304Y | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV55623593; called by muse, mutect2, varscan2
- MFSD6 | c.1457C>A p.S486* | Nonsense Mutation (SNP) | VAF 39/120 reads (33%) | catalogued as COSV55624286, COSV99854981; called by muse, mutect2, varscan2
- MGAT4A | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.724); catalogued as COSV53848252, COSV53848537; called by muse, mutect2, varscan2
- MGAT5B | c.1656C>A p.F552L (on ENST00000569840 / NM_001199172.2; = p.F550L on NM_144677.3) | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV56931490; called by muse, mutect2
- MICALL2 | c.1481G>C p.S494T | Missense Mutation (SNP) | VAF 17/362 reads (5%) | SIFT tolerated (0.74); PolyPhen benign (0.057); catalogued as COSV52516641; called by muse, mutect2
- MIER1 | c.1393G>C p.E465Q (on ENST00000355356 / NM_001077701.3; = p.E482Q on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.366); catalogued as COSV62530283; called by muse, mutect2, varscan2
- MINDY2 | c.242C>G p.S81C | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV57507384; called by muse, mutect2, varscan2
- MIS18BP1 | c.2146G>A p.E716K | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV60371597; called by muse, mutect2, varscan2
- MIS18BP1 | c.1938G>C p.K646N | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV60371608; called by muse, mutect2
- MLH1 | c.2149G>C p.E717Q | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.546); catalogued as CD163908, COSV51614093, COSV51620187; called by muse, mutect2, varscan2
- MLLT3 | c.1576A>C p.I526L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV63498825; called by muse, mutect2
- MMAB | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.406); catalogued as COSV57170575; called by muse, mutect2, varscan2
- MME | c.215A>G p.N72S | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.428); catalogued as COSV64708505; called by muse, mutect2, varscan2
- MMP17 | c.1438G>C p.D480H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62179750, COSV62180152; called by muse, mutect2, varscan2
- MPEG1 | c.1874C>G p.S625C | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.315); catalogued as COSV57092182; called by muse, mutect2
- MPHOSPH9 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56621311; called by muse, mutect2, varscan2
- MPL | c.695C>G p.S232* | Nonsense Mutation (SNP) | VAF 24/139 reads (17%) | catalogued as COSV65246544; called by muse, mutect2, varscan2
- MPZL3 | c.553G>T p.A185S | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1001162400, COSV54053548; called by muse, mutect2
- MRNIP | c.657C>G p.I219M | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV52973846; called by muse, varscan2
- MRPL51 | c.141G>A p.W47* | Nonsense Mutation (SNP) | VAF 16/140 reads (11%) | catalogued as COSV99975172; called by muse, mutect2, varscan2
- MTA2 | c.720G>C p.R240S | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as COSV53872951; called by muse, mutect2
- MTA2 | c.438G>C p.E146D | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV53872961, COSV53874648; called by muse, mutect2, varscan2
- MTDH | c.1409G>C p.R470T | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.167); catalogued as COSV60344984; called by muse, mutect2, varscan2
- MTMR3 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV60305951; called by muse, mutect2, varscan2
- MTRF1 | c.170G>T p.W57L | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV53481729; called by muse, mutect2, varscan2
- MTSS1 | c.1805G>C p.G602A | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.279); catalogued as COSV52675083, COSV52675401; called by muse, mutect2
- MTUS2 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.207); catalogued as COSV101462332, COSV70917812; called by muse, mutect2, varscan2
- MTUS2 | c.1219G>C p.D407H | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as COSV70914618, COSV70915084, COSV70917815; called by muse, mutect2, varscan2
- MUC16 | c.24191C>G p.S8064C | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.633); catalogued as COSV101200691, COSV67476204, COSV67492652; called by muse, mutect2
- MUC16 | c.18947A>G p.Y6316C | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.325); catalogued as COSV67476211; called by muse, mutect2
- MUC16 | c.16331C>G p.S5444* | Nonsense Mutation (SNP) | VAF 26/304 reads (9%) | catalogued as COSV101197932; called by muse, mutect2
- MUC16 | c.7481C>T p.S2494F | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.102); catalogued as rs776617426, COSV67476215; called by mutect2, varscan2
- MUC4 | c.793A>C p.T265P | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.517); catalogued as COSV62161786; called by muse, mutect2, varscan2
- MUC5B | c.5509G>T p.E1837* | Nonsense Mutation (SNP) | VAF 13/64 reads (20%) | catalogued as COSV101499998, COSV71589915; called by muse, mutect2, varscan2
- MX1 | c.467G>C p.G156A | Missense Mutation (SNP) | VAF 13/159 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.232); catalogued as COSV55819814; called by muse, mutect2
- MYCBP2 | c.3822-1G>C p.X1274_splice (on ENST00000357337; = p.X1312_splice on NM_015057.5) | Splice Site (SNP) | VAF 11/39 reads (28%) | catalogued as COSV62026521; called by muse, mutect2, varscan2
- MYCBP2 | c.2557G>C p.E853Q (on ENST00000357337; = p.E891Q on NM_015057.5) | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.954); catalogued as COSV62022844; called by muse, mutect2
- MYCN | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV99808012; called by muse, mutect2
- MYG1 | c.409C>G p.L137V | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.036); catalogued as COSV52933383; called by muse, mutect2
- MYH1 | c.3859G>C p.E1287Q | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.562); catalogued as COSV56848108; called by muse, mutect2, varscan2
- MYH11 | c.332C>G p.S111* | Nonsense Mutation (SNP) | VAF 6/78 reads (8%) | catalogued as COSV100257584; called by muse, mutect2
- MYH9 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 35/230 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.22); catalogued as rs767088377, COSV53382430; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH9 | c.1011G>A p.M337I | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV53388783; called by muse, mutect2, varscan2
- MYO1C | c.157C>A p.L53M (on ENST00000648651 / NM_001080779.2; = p.L18M on NM_033375.5) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1417833713, COSV62999767; called by muse, mutect2, varscan2
- MYO1D | c.1859G>C p.R620T | Missense Mutation (SNP) | VAF 17/219 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV59016763; called by muse, mutect2
- MYO1D | c.1478C>G p.S493* | Nonsense Mutation (SNP) | VAF 9/105 reads (9%) | catalogued as COSV100553386; called by muse, mutect2
- MYO1F | c.1554G>C p.E518D | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.075); catalogued as COSV57796793; called by muse, mutect2
- MYO1G | c.603C>A p.F201L | Missense Mutation (SNP) | VAF 14/414 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV51853253, COSV51855428; called by muse, mutect2
- MYO5A | c.3959G>T p.R1320I | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV100697260; called by muse, mutect2
- MYO5C | c.919C>G p.Q307E | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV55908467; called by muse, mutect2, varscan2
- MYO7A | c.3580C>A p.L1194I | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV68685355; called by muse, mutect2
- MYO9B | c.4735G>C p.E1579Q | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.239); catalogued as rs1223943947, COSV101261208, COSV68282552; called by muse, mutect2
- MYPN | c.895C>G p.Q299E | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV62735243; called by muse, mutect2, varscan2
- MZF1 | c.1075G>C p.D359H | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.597); catalogued as COSV99285026; called by muse, mutect2
- N4BP1 | c.2177G>A p.R726K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as COSV52211588; called by muse, mutect2, varscan2
- N4BP2 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV54703838; called by muse, mutect2, varscan2
- NAA15 | c.1332C>G p.I444M | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56720692; called by muse, mutect2
- NAF1 | c.94C>G p.P32A | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as COSV99918869; called by muse, mutect2, varscan2
- NALCN | c.4002G>C p.K1334N | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51945763, COSV51960706; called by muse, varscan2
- NAPRT | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); catalogued as rs962870447, COSV99063644; called by muse, mutect2, varscan2
- NAT10 | c.1607C>G p.S536C | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57664735; called by muse, mutect2
- NAV1 | c.2932G>A p.E978K | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as rs773882976, COSV55220498, COSV55226806; called by muse, mutect2, varscan2
- NBAS | c.3200C>G p.S1067C | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.868); catalogued as rs1446051160, COSV55736909; called by muse, mutect2
- NBEA | c.8484G>C p.L2828F | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as COSV59797556; called by muse, mutect2, varscan2
- NCKAP1 | c.1681T>A p.S561T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.114); catalogued as COSV62941859; called by muse, mutect2, varscan2
- NCOR1 | c.6848G>C p.G2283A | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.262); catalogued as COSV51981993, COSV99252735; called by muse, mutect2, varscan2
- NDUFAF3 | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV58245625; called by muse, mutect2, varscan2
- NEB | c.9047G>A p.R3016Q | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.535); catalogued as rs200930670, COSV51430018; called by muse, mutect2, varscan2
- NEK11 | c.1667C>A p.P556Q | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.36); catalogued as COSV67282977; called by muse, mutect2
- NELFA | c.573G>C p.Q191H (on ENST00000542778; = p.Q180H on NM_005663.5) | Missense Mutation (SNP) | VAF 20/391 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as COSV61606628; called by muse, mutect2
- NEURL1 | c.1280C>T p.S427L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63913770; called by muse, mutect2, varscan2
- NF1 | c.4468G>T p.D1490Y (on ENST00000358273 / NM_001042492.3; = p.D1469Y on NM_000267.3) | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV62206020, COSV62208696; called by muse, mutect2, varscan2
- NF1 | c.7712G>C p.R2571T (on ENST00000358273 / NM_001042492.3; = p.R2550T on NM_000267.3) | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.063); catalogued as COSV100645957; called by muse, mutect2
- NFATC1 | c.1034C>T p.S345L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs771768091, COSV53703322; called by muse, mutect2, varscan2
- NFE2L3 | c.2016C>G p.I672M | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV50231063, COSV50233301; called by muse, mutect2
- NGEF | c.1876C>A p.Q626K | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.609); catalogued as COSV50919981, COSV50929099; called by muse, mutect2, varscan2
- NHLRC2 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.024); catalogued as COSV65175245; called by muse, mutect2, varscan2
- NIM1K | c.703C>A p.P235T | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58142971; called by muse, mutect2
- NINL | c.3429G>C p.Q1143H | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV54004735, COSV54008927; called by muse, mutect2, varscan2
- NMNAT3 | c.191G>A p.R64Q (on ENST00000296202 / NM_001320512.1; = p.R27Q on NM_178177.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs368218373; called by muse, mutect2, varscan2
- NMRAL1 | c.606G>C p.K202N | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.992); catalogued as COSV52060426; called by muse, mutect2, varscan2
- NOD1 | c.1959C>G p.I653M | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV56113366; called by muse, mutect2
- NOL6 | c.2620G>A p.E874K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV99954408; called by muse, mutect2
- NOL9 | c.1924G>C p.A642P | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); catalogued as COSV66626439; called by muse, mutect2, varscan2
- NOP14 | c.829G>C p.E277Q | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.974); catalogued as rs1343838654, COSV58626034; called by muse, mutect2, varscan2
- NOTCH2 | c.5278G>A p.D1760N | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.413); catalogued as rs1034013158, COSV56695333; called by muse, mutect2, varscan2
- NPPA | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV56741237; called by muse, mutect2, varscan2
- NR0B1 | c.1317C>G p.I439M | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV66764283; called by muse, mutect2
- NRBP1 | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.119); catalogued as COSV51994834; called by muse, mutect2
- NRDC | c.3490G>A p.E1164K | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.225); catalogued as COSV61405870; called by muse, mutect2
- NRG3 | c.1999G>T p.D667Y (on ENST00000404547 / NM_001370084.1; = p.D643Y on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.684); catalogued as COSV64570211; called by muse, mutect2, varscan2
- NRXN1 | c.3448G>A p.D1150N | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58457664, COSV58465862; called by muse, mutect2, varscan2
- NRXN2 | c.4412C>T p.P1471L | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.06); PolyPhen benign (0.09); catalogued as rs370931744; called by muse, varscan2
- NSD1 | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as COSV61776327; called by muse, mutect2
- NSDHL | c.646A>G p.I216V | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV64744412; called by muse, mutect2, varscan2
- NT5E | c.1586C>G p.S529C | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV57629115; called by muse, mutect2
- NUDT19 | c.240C>A p.F80L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as COSV67959600; called by muse, varscan2
- NUDT19 | c.288C>G p.F96L | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV67959602; called by muse, varscan2
- NUFIP1 | c.371C>G p.S124C | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.436); catalogued as COSV100742108; called by muse, mutect2, varscan2
- NUP210L | c.4423C>T p.P1475S | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV55150941; called by muse, mutect2
- NUP42 | c.1212G>C p.K404N | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV51730313; called by muse, mutect2, varscan2
- NUSAP1 | c.1075G>C p.D359H | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52971838; called by muse, mutect2
- OBSCN | c.10649G>C p.R3550T | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV52790019; called by muse, mutect2, varscan2
- OCRL | c.2382C>A p.F794L | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.823); catalogued as rs747535429, COSV63981202; called by muse, mutect2, varscan2
- OMA1 | c.955C>T p.H319Y | Missense Mutation (SNP) | VAF 19/257 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV62254903, COSV62256357; called by muse, mutect2
- OPA1 | c.2791G>C p.D931H (on ENST00000361510 / NM_130837.3; = p.D876H on NM_015560.3) | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62481655; called by muse, mutect2, varscan2
- OPLAH | c.3866G>C p.*1289Sext*? | Nonstop Mutation (SNP) | VAF 19/80 reads (24%) | catalogued as COSV66299248; called by muse, mutect2, varscan2
- OPN1SW | c.230C>G p.S77C | Missense Mutation (SNP) | VAF 18/209 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV50822343; called by muse, mutect2
- OR10J5 | c.793A>T p.S265C | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.886); catalogued as COSV58386636; called by muse, mutect2, varscan2
- OR1G1 | c.905G>C p.R302T | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV61030347, COSV61030374; called by muse, mutect2, varscan2
- OR2W1 | c.265G>C p.D89H | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV65851706, COSV65851893; called by muse, mutect2
- OR4C16 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 69/326 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.187); catalogued as rs150706012, COSV58940789; called by muse, mutect2, varscan2
- OR4P4 | c.478C>G p.L160V | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV58922662; called by muse, mutect2
- OR51I1 | c.831G>C p.M277I | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as COSV66507349, COSV66508350, COSV66508368; called by muse, mutect2, varscan2
- OR52E8 | c.594C>G p.I198M | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs747421307, COSV66208002; called by muse, mutect2, varscan2
- OR52L1 | c.623C>G p.S208* | Nonsense Mutation (SNP) | VAF 9/163 reads (6%) | catalogued as COSV59986997; called by muse, mutect2
- OR6C4 | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1327650396, COSV67793080; called by muse, mutect2, varscan2
- OR8G5 | c.650C>G p.S217C | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.872); catalogued as COSV100422199; called by muse, mutect2, varscan2
- OTOF | c.3814G>A p.E1272K (on ENST00000272371 / NM_194248.3; = p.E505K on NM_004802.4) | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.122); catalogued as COSV55507785; called by muse, mutect2, varscan2
- OTOP2 | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 35/234 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.147); catalogued as COSV58882453; called by muse, mutect2, varscan2
- P2RY10 | c.235G>T p.A79S | Missense Mutation (SNP) | VAF 14/195 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50681448, COSV50685739; called by muse, mutect2
- PAPSS2 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.108); catalogued as rs1355794195, COSV63263963; called by muse, mutect2, varscan2
- PARS2 | c.1041C>G p.I347M | Missense Mutation (SNP) | VAF 19/207 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs547116468, COSV64883415, COSV64883679; called by muse, mutect2
- PARS2 | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs1484527966, COSV64883684; called by muse, mutect2
- PASK | c.3668-1G>C p.X1223_splice | Splice Site (SNP) | VAF 36/107 reads (34%) | catalogued as COSV52155079; called by muse, mutect2, varscan2
- PASK | c.1404G>C p.Q468H | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.364); catalogued as COSV52155111; called by muse, mutect2
953 further variants in this file (547 protein-altering or splice-affecting, 364 silent, 42 other) are not listed here.
